Somatic mutation profile of tumor specimen TCGA-3X-AAVC-01A (aliquot TCGA-3X-AAVC-01A-21D-A417-09) from TCGA case TCGA-3X-AAVC, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Extrahepatic bile duct; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 72.5 years (26,493 days).
Specimen TCGA-3X-AAVC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47e6fde3-36b7-4282-9b6c-3671ab0c3c97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3X-AAVC-10A (Blood Derived Normal), aliquot TCGA-3X-AAVC-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da6cf7e2-4e2a-48a9-bd70-7a2f647345c9

The open-access MAF lists 55 somatic variants for this specimen: 43 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 9, Frame Shift Del 3, In Frame Del 2, 5'Flank 2, Nonsense Mutation 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 13/22 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANGPT1 | c.821G>T p.G274V | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV52445945; called by muse, mutect2, varscan2
- FAM184A | c.2852T>C p.M951T | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs1253914864; called by muse, mutect2, varscan2
- FGF16 | c.378G>A p.S126= | Splice Region (SNP) | VAF 20/64 reads (31%) | catalogued as rs781972271, CS149597; called by muse, mutect2, varscan2
- GNA12 | c.649G>A p.V217I | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs201475988; called by muse, mutect2, varscan2
- HAAO | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1367447151; called by muse, mutect2, varscan2
- ICAM1 | c.236A>G p.Y79C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53424189; called by muse, mutect2, varscan2
- KAT14 | c.1504A>G p.R502G | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1166373796, COSV66606922; called by muse, mutect2, varscan2
- KIF1B | c.5177G>A p.R1726H (on ENST00000377086 / NM_001365952.1; = p.R1680H on NM_015074.3) | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778439251; called by muse, mutect2, varscan2
- MUC6 | c.6387_6389del p.S2130del | In Frame Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs765184193; called by pindel, varscan2
- NISCH | c.854C>T p.T285I | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as rs1174118154; called by muse, mutect2, varscan2
- NT5DC2 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs781672571; called by mutect2, varscan2
- PAFAH1B1 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1451577273, COSV68209986; called by muse, mutect2, varscan2
- TMCC1 | c.1694A>T p.Q565L (on ENST00000393238 / NM_001349268.2; = p.Q241L on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV61438329, COSV61439157; called by muse, mutect2
- USP21 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.048); catalogued as COSV57091149; called by muse, mutect2, varscan2
- VIRMA | c.1064A>G p.Y355C | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.929); catalogued as COSV52589754; called by muse, mutect2, varscan2
- AFDN | c.935A>G p.K312R | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2
- AHNAK2 | c.9857A>G p.D3286G | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- APOBEC4 | c.295T>A p.F99I | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- B3GNT2 | c.10G>C p.G4R | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated, low confidence (0.55); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- BEND7 | c.218G>C p.G73A | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- BIN1 | c.1177C>A p.L393M | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); called by muse, varscan2
- CLSTN1 | c.560C>T p.A187V (on ENST00000377298 / NM_001009566.3; = p.A177V on NM_014944.4) | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- COL6A3 | c.1084A>G p.I362V | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH5 | c.7273C>A p.R2425S | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ENC1 | c.1172del p.Y391Lfs*21 | Frame Shift Del (DEL) | VAF 12/18 reads (67%) | called by mutect2, varscan2
- HRNR | c.2312G>C p.G771A | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- IFNL3 | c.578A>G p.D193G | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- LNX2 | c.2020C>T p.Q674* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- LRRCC1 | c.3058C>A p.Q1020K | Missense Mutation (SNP) | VAF 100/169 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- MAP7D2 | c.1823del p.T608Ifs*42 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | called by mutect2, pindel, varscan2
- MSN | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- NAV1 | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ONECUT2 | c.998_1000del p.I333del | In Frame Del (DEL) | VAF 18/28 reads (64%) | called by mutect2, pindel, varscan2
- OR9I1 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.054); called by mutect2, varscan2
- PBRM1 | c.4077_4086del p.P1360Lfs*21 | Frame Shift Del (DEL) | VAF 14/23 reads (61%) | called by mutect2, pindel, varscan2
- RFESD | c.416A>G p.K139R | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0); called by mutect2, varscan2
- SMG1 | c.1084G>T p.G362C | Missense Mutation (SNP) | VAF 42/325 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF2 | c.1942A>G p.M648V | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- UNC13C | c.3577T>C p.F1193L | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- USP29 | c.2373C>A p.N791K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.191); called by muse, mutect2
- ZBTB24 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- ZNF250 | c.999C>A p.H333Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATF7IP | c.72G>A p.Q24= | Silent (SNP) | VAF 53/79 reads (67%) | called by muse, mutect2, varscan2
- BRD9 | c.1788G>A p.K596= | Silent (SNP) | VAF 27/302 reads (9%) | catalogued as COSV100057287; called by muse, mutect2
- DNASE1L1 | c.354T>C p.D118= | Silent (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- FIP1L1 | c.582G>A p.R194= | Silent (SNP) | VAF 47/102 reads (46%) | catalogued as rs768710724; called by muse, mutect2, varscan2
- POM121 | c.3696C>T p.T1232= (on ENST00000434423; = p.T967= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/92 reads (45%) | called by muse, mutect2, varscan2
- SH3GL1 | c.828C>G p.P276= | Silent (SNP) | VAF 23/40 reads (58%) | called by muse, mutect2, varscan2
- TFAP2D | c.666T>C p.S222= | Silent (SNP) | VAF 16/27 reads (59%) | called by muse, mutect2, varscan2
- TMEM260 | c.99C>T p.F33= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs754485638; called by muse, mutect2, varscan2
- TSPAN18 | c.555C>T p.D185= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs558236701; called by muse, mutect2, varscan2
- HERC2P3 | chr15:20457676 C>G | 5'Flank (SNP) | VAF 20/191 reads (10%) | called by muse, mutect2
- L1CAM | c.-109+1823C>T | Intron (SNP) | VAF 10/26 reads (38%) | catalogued as rs375989685; called by muse, mutect2, varscan2
- Y_RNA | chr14:50083666 ins TC | 5'Flank (INS) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
